Surgical pathology report (de-identified scan), TCGA case TCGA-62-A472, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-A472-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, right, lower lobe: 14.0 x 4.0 x 2.8 cm

tumor 1: 2.5 x 2.2 x 2.1 cm

tumor 2: 1.5.0 x 1.4 x 1.3 cm

Diagnosis:

Both tumors Adenocarcinoma (NOS)

Tumor 1 infiltrates and breaks pleura visceralis

pT3, pN0 (0/2), pMx, G3

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: lung, lower lobe C34.3

hw
9/24/12

Pathologist:

P for Malignancy History		☒
Dupl/Synchronous Primaries Noted		☒

hw
9/24/12

Source: NCI Genomic Data Commons file d1e34a8f-17ac-4839-9e89-145fd267e8ba (TCGA-62-A472.1C47AD8C-F1EB-4B7E-9633-3260EF8CEAE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).